Somatic mutation profile of tumor specimen HTMCP-03-06-02082-01A (aliquot HTMCP-03-06-02082-01A-01D-4427) from CGCI case HTMCP-03-06-02082, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 49.6 years (18,106 days).
Specimen HTMCP-03-06-02082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8549b8b5-5530-4b17-a295-c4bf7e383848.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02082-10A (Blood Derived Normal), aliquot HTMCP-03-06-02082-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc3ed919-0704-43da-abf0-df0389dc1370

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 7, Intron 3, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ARID2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 50/215 reads (23%) | catalogued as COSV57596554, COSV57617903; called by muse, mutect2, varscan2
- CARD11 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1286226733; called by muse, mutect2, varscan2
- CEP104 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs148927222; called by muse, mutect2, varscan2
- CSMD1 | c.9052C>T p.R3018W (on ENST00000520002; = p.R3017W on NM_033225.6) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767170676, COSV59306240; called by muse, mutect2, varscan2
- DISP2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs748735816, COSV51120897; called by muse, mutect2, varscan2
- EPHB1 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67666703; called by muse, mutect2, varscan2
- FAT3 | c.2702C>G p.S901C | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.605); catalogued as COSV53081653; called by muse, mutect2, varscan2
- FAT4 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV67896927; called by muse, mutect2, varscan2
- GREB1 | c.5281C>T p.R1761C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs1465479883, COSV52186983; called by muse, mutect2, varscan2
- GRIN2A | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs199696775, COSV58054811; called by muse, mutect2, varscan2
- KCNB2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV101578623; called by muse, mutect2, varscan2
- LAMB1 | c.5255G>C p.R1752T | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99227623; called by muse, varscan2
- OR13C2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV101604874; called by muse, mutect2, varscan2
- PER1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.98); catalogued as rs1465601716; called by muse, mutect2, varscan2
- PTPRB | c.5183G>C p.R1728T | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs764303487; called by muse, mutect2, varscan2
- SRRM2 | c.7717G>A p.E2573K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51940149; called by muse, mutect2, varscan2
- TRAPPC8 | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as COSV51967480; called by muse, mutect2, varscan2
- AAK1 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- ATMIN | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- CAMSAP1 | c.4370C>T p.S1457L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CCDC160 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CNOT8 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HLA-B | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LYST | c.8948-1G>A p.X2983_splice | Splice Site (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- MAP3K12 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- MKI67 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PKHD1L1 | c.9608G>A p.S3203N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- STRBP | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TJAP1 | c.1453G>A p.E485K (on ENST00000372445 / NM_001146016.1; = p.E475K on NM_080604.3) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- UPF3B | c.816G>C p.R272S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- XPOT | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CSMD1 | c.8607C>T p.A2869= (on ENST00000520002; = p.A2868= on NM_033225.6) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs779219870, COSV59338330; called by muse, mutect2, varscan2
- DCBLD2 | c.2103C>T p.F701= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- MYO1C | c.3123G>A p.S1041= (on ENST00000648651 / NM_001080779.2; = p.S1006= on NM_033375.5) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs370307852; called by muse, mutect2, varscan2
- SLITRK2 | c.981C>T p.I327= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- TET1 | c.4176G>A p.Q1392= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- USP51 | c.282C>T p.S94= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- WDR6 | c.2022C>T p.L674= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-351C>T | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- REG4 | c.165+142G>A | Intron (SNP) | VAF 70/142 reads (49%) | called by muse, mutect2, varscan2
- TPTE2 | c.1395+669C>A | Intron (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
